Somatic mutation profile of tumor specimen TCGA-FP-7998-01A (aliquot TCGA-FP-7998-01A-11D-2201-08) from TCGA case TCGA-FP-7998, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.5 years (28,302 days).
Specimen TCGA-FP-7998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44f8b6e3-3673-4586-bed2-9a1cb1f594f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-7998-10A (Blood Derived Normal), aliquot TCGA-FP-7998-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a97110c-5fff-4ca5-a034-cf4674a1218e

The open-access MAF lists 64 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Nonsense Mutation 6, Splice Site 3, Translation Start Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4606G>A p.A1536T | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as rs772332005, COSV56846274; called by muse, mutect2
- ACTN2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV63978276; called by mutect2, varscan2
- AFF4 | c.2552C>T p.T851M | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as rs769422062, COSV54793685; called by muse, mutect2, varscan2
- AHNAK2 | c.8740C>T p.P2914S | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV60930595; called by muse, mutect2, varscan2
- ALDH1L1 | c.2419G>A p.G807R | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368465875; called by muse, mutect2, varscan2
- ANK1 | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 20/322 reads (6%) | catalogued as CM014315, COSV55878815; called by muse, mutect2
- ARID1A | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV61373983; called by muse, mutect2, varscan2
- ATP8B2 | c.2071G>C p.E691Q (on ENST00000672630; = p.E658Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV59248928; called by muse, mutect2, varscan2
- BCHE | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs1340162283, COSV100012733, COSV52262564; called by muse, mutect2
- CDH12 | c.2280A>C p.E760D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66390541; called by muse, mutect2
- CDH16 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV55339743; called by muse, varscan2
- CDH7 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868447230, COSV59894705; called by muse, mutect2, varscan2
- CHRNE | c.345-1G>C p.X115_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53416714, COSV53420125; called by muse, mutect2
- CIT | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV55883170; called by muse, mutect2
- CLTCL1 | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV54239310; called by muse, mutect2
- COL19A1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416918271, COSV59588444; called by muse, mutect2, varscan2
- DNAH14 | c.879+2T>C p.X293_splice (on ENST00000445597; = p.X166_splice on NM_144989.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as rs1428724544, COSV64781099; called by muse, mutect2
- GAPVD1 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as COSV52927460; called by muse, mutect2, varscan2
- IRS4 | c.2381G>T p.R794I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV64535978; called by muse, mutect2, varscan2
- KALRN | c.3655C>G p.H1219D | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV53780409; called by muse, mutect2
- LMTK2 | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV52003952; called by muse, mutect2, varscan2
- LRRN1 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV60016345; called by muse, mutect2, varscan2
- MAMLD1 | c.1790A>T p.Q597L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.529); catalogued as COSV53376712; called by muse, mutect2
- MEF2C | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60939761; called by muse, mutect2, varscan2
- MMP19 | c.1289C>A p.S430* | Nonsense Mutation (SNP) | VAF 30/210 reads (14%) | catalogued as rs372055008, COSV59450945; called by muse, mutect2, varscan2
- MYO18B | c.2779A>T p.I927F | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59148689; called by muse, mutect2, varscan2
- NCDN | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as COSV57850657; called by muse, mutect2, varscan2
- NINJ2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1232958775, COSV56758013; called by muse, mutect2
- NLRP1 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs760487890, COSV52564635; called by muse, mutect2, varscan2
- NUFIP1 | c.1139-2A>T p.X380_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV64792258; called by muse, varscan2
- PCDH18 | c.1611A>C p.E537D | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV61272198; called by muse, mutect2, varscan2
- PDE10A | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63106187; called by muse, mutect2, varscan2
- PHOX2A | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV53359364; called by muse, mutect2
- PLK1 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV55622568; called by muse, mutect2, varscan2
- PPP3CA | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV59931566; called by muse, mutect2
- PRB3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 35/496 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV54393414; called by muse, mutect2
- PTPRD | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs547908736, COSV61981604; called by muse, mutect2, varscan2
- QKI | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51700367; called by muse, mutect2, varscan2
- QSOX2 | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62395311; called by muse, mutect2, varscan2
- SAGE1 | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV100187712, COSV61017977; called by muse, mutect2, varscan2
- SETD6 | c.623G>A p.R208H (on ENST00000219315 / NM_001160305.4; = p.R184H on NM_024860.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50746386; called by muse, mutect2, varscan2
- SP7 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58192064; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs748467821; called by mutect2, varscan2
- SUOX | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as COSV56271600; called by muse, mutect2, varscan2
- TFAP2D | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV50458021, COSV99145824; called by muse, mutect2, varscan2
- WDR81 | c.4339C>T p.P1447S (on ENST00000409644 / NM_001163809.2; = p.P396S on NM_152348.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58488355; called by muse, mutect2
- ZNF251 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.439); catalogued as COSV52956815, COSV52959249; called by muse, mutect2
- ZNF804B | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60855536; called by muse, mutect2, varscan2
- ADAM30 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- CPXCR1 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FSCB | c.2233C>A p.Q745K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2
- AMER1 | c.228A>G p.G76= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV57653801; called by muse, mutect2
- BFSP1 | c.1407G>T p.R469= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1363137129, COSV64901898; called by muse, mutect2, varscan2
- CTR9 | c.393G>A p.L131= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV63729675; called by muse, mutect2
- DNAJC7 | c.882T>C p.A294= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV57270375; called by muse, mutect2, varscan2
- GRIN2D | c.567C>T p.A189= | Silent (SNP) | VAF 31/402 reads (8%) | catalogued as COSV54382270; called by muse, mutect2
- MCOLN1 | c.1119C>T p.I373= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs765687408, COSV51179385; called by muse, mutect2
- MRM1 | c.507C>T p.L169= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1237486948; called by muse, mutect2, varscan2
- PRL | c.147C>T p.R49= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs375151169; called by muse, mutect2, varscan2
- SLC6A17 | c.1425C>T p.I475= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs200290904; called by muse, mutect2
- UBR4 | c.9186C>T p.F3062= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV64383590; called by muse, mutect2
- ZNF423 | c.3120G>A p.T1040= (on ENST00000563137 / NM_001379286.1; = p.T1032= on NM_015069.4) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs145829157, COSV52189873; called by muse, mutect2, varscan2
- IKBIP | c.297+7700G>A | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as rs200441162, COSV100141848; called by mutect2, varscan2
